CCDI case PBBUIL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/dcc383ef-13d2-41ce-bd21-3c3b642fe723

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 1.3 years (485 days).

Biospecimens (3 samples)
- Sample 0DHFL0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHFLR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHFP3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
